MMRF case MMRF_1131 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/44881089-7fa9-49e0-b71a-fd56bea9b5bd

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 41 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 41.5 years (15,160 days); ISS stage: II; Days to last known disease status: 444 days (1.2 years); Days to last follow up: 444 days (1.2 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 74 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 7 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 8 days; Days to treatment end: 12 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 22 days; Days to treatment end: 74 days.
   Treatment given: Therapeutic agents: Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 22 days; Days to treatment end: 269 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 100 days; Days to treatment end: 114 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 100 days; Days to treatment end: 175 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 179 days; Days to treatment end: 269 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 186 days; Days to treatment end: 256 days.
   Treatment given: Therapeutic agents: Pomalidomide + Prednisone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 312 days; Days to treatment end: 333 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 444.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -3: M Protein 4.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.99 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.07 mg/dL; Immunoglobulin G 2.86 g/L; Immunoglobulin A 64 g/L; Immunoglobulin M 0.17 g/L; Beta 2 Microglobulin 4.4 µg/mL; Lactate Dehydrogenase 1.3 µkat/L; Hemoglobin 5.7 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 119 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.53 mmol/L; Albumin 26 g/L; Total Protein 11.2 g/dL; Glucose 7.04 mmol/L.
- Day 99: M Protein 0.56 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.12 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.1 mg/dL; Immunoglobulin G 5.91 g/L; Immunoglobulin A 4.74 g/L; Immunoglobulin M 0.43 g/L; Lactate Dehydrogenase 1.78 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 256 ×10⁹/L; Creatinine 52.2 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.35 mmol/L; Albumin 39 g/L; Total Protein 6.7 g/dL; Glucose 5.06 mmol/L.
- Day 169: M Protein 1.12 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.17 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.93 mg/dL; Immunoglobulin G 6.34 g/L; Immunoglobulin A 18.5 g/L; Immunoglobulin M 0.46 g/L; Hemoglobin 6.76 mmol/L; Leukocytes 37.1 ×10⁹/L; Absolute Neutrophil 35.2 ×10⁹/L; Platelets 57 ×10⁹/L; Creatinine 51.3 µmol/L; Blood Urea Nitrogen 1.43 mmol/L; Calcium 2.3 mmol/L; Glucose 4.62 mmol/L.
- Day 268: M Protein 1.48 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.16 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.12 mg/dL; Immunoglobulin G 4.89 g/L; Immunoglobulin A 23.3 g/L; Immunoglobulin M 0.27 g/L; Hemoglobin 6.32 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 199 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.4 mmol/L; Albumin 35 g/L; Total Protein 8.6 g/dL; Glucose 5.61 mmol/L.
- Day 345: M Protein 1.94 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.74 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.09 mg/dL; Immunoglobulin G 3.85 g/L; Immunoglobulin A 37 g/L; Immunoglobulin M 0.29 g/L; Hemoglobin 6.39 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 248 ×10⁹/L; Creatinine 46 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.28 mmol/L; Glucose 4.95 mmol/L.
- Day 415 (ECOG 0): M Protein 2.89 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.94 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.07 mg/dL; Immunoglobulin G 3.16 g/L; Immunoglobulin A 53.3 g/L; Immunoglobulin M 0.19 g/L; Hemoglobin 6.45 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 197 ×10⁹/L; Creatinine 58.3 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.4 mmol/L; Albumin 29 g/L; Total Protein 10.4 g/dL; Glucose 4.95 mmol/L.

Other clinical attributes
- Day -3: Weight: 62 kg; Height: 161 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1131_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 345 days.
- Sample MMRF_1131_2_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 345 days.
